Somatic mutation profile of tumor specimen TCGA-VQ-A8P3-01A (aliquot TCGA-VQ-A8P3-01A-11D-A364-08) from TCGA case TCGA-VQ-A8P3, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Tubular adenocarcinoma; Tissue or organ of origin: Body of stomach; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 72.8 years (26,582 days).
Specimen TCGA-VQ-A8P3-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6f8f6f2b-f164-4704-9722-512f5a3f7c97.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VQ-A8P3-10A (Blood Derived Normal), aliquot TCGA-VQ-A8P3-10A-01D-A362-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a3a3f85d-a63c-4bcf-a6a3-161189e786a7

The open-access MAF lists 302 somatic variants for this specimen: 233 protein-altering or splice-affecting, 64 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 216, Silent 64, Nonsense Mutation 5, Splice Site 3, Frame Shift Del 3, Intron 2, Frame Shift Ins 2, In Frame Del 2, 3'UTR 1, 5'UTR 1, Splice Region 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BMPR1A | c.1480C>T p.R494* | Nonsense Mutation (SNP) | VAF 20/101 reads (20%) | catalogued as rs786201040, CM135237, COSV64404915; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCA12 | c.757T>G p.F253V | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV55960333, COSV99788255; called by muse, mutect2, varscan2
- ABCC9 | c.106T>G p.F36V | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.826); catalogued as COSV99684443; called by muse, mutect2, varscan2
- ACADL | c.256A>C p.S86R | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.951); catalogued as COSV99284526; called by muse, mutect2, varscan2
- ACP7 | c.220G>A p.A74T | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.013); catalogued as rs778099811, COSV58700867; called by muse, mutect2
- ACSS3 | c.1591T>G p.F531V | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.575); catalogued as COSV99698288; called by muse, mutect2, varscan2
- ACTN2 | c.1786A>C p.S596R | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT tolerated (0.46); PolyPhen benign (0.039); catalogued as COSV100856528, COSV63978620; called by muse, mutect2, varscan2
- ADAM2 | c.1223T>G p.L408R | Missense Mutation (SNP) | VAF 27/117 reads (23%) | SIFT tolerated (0.68); PolyPhen benign (0.006); catalogued as rs759673514, COSV55861720, COSV99696709; called by muse, mutect2, varscan2
- ADAMTS20 | c.2989T>G p.F997V | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.557); catalogued as COSV101166067; called by muse, mutect2, varscan2
- AFF2 | c.1701A>C p.E567D | Missense Mutation (SNP) | VAF 72/133 reads (54%) | SIFT tolerated (0.11); PolyPhen benign (0.017); catalogued as COSV99661918; called by muse, mutect2, varscan2
- AMPH | c.569A>G p.E190G | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100340859; called by muse, mutect2, varscan2
- ANKEF1 | c.1399C>T p.R467W | Missense Mutation (SNP) | VAF 33/123 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV65692317; called by muse, mutect2, varscan2
- AR | c.730T>G p.S244A | Missense Mutation (SNP) | VAF 11/19 reads (58%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as CM058323, COSV101017372; called by muse, mutect2, varscan2
- ARID2 | c.3121C>T p.Q1041* | Nonsense Mutation (SNP) | VAF 18/90 reads (20%) | catalogued as COSV57595998; called by muse, mutect2, varscan2
- ARMC4 | c.2291T>G p.L764R | Missense Mutation (SNP) | VAF 29/104 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100536315; called by muse, mutect2, varscan2
- BCAS2 | c.409G>C p.V137L | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT tolerated (0.54); PolyPhen benign (0.01); catalogued as COSV101058494, COSV65767227; called by muse, mutect2, varscan2
- BMP10 | c.832C>A p.Q278K | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV99770267; called by muse, mutect2, varscan2
- BPIFB6 | c.920A>C p.K307T | Missense Mutation (SNP) | VAF 21/116 reads (18%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.951); catalogued as COSV100848482; called by muse, mutect2, varscan2
- BRINP1 | c.1099A>C p.S367R | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV99774423; called by muse, mutect2, varscan2
- C1QTNF2 | c.638A>G p.K213R (on ENST00000393975; = p.K168R on NM_031908.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 36/119 reads (30%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.992); catalogued as COSV101220824; called by muse, mutect2, varscan2
- C1orf87 | c.986G>A p.R329Q | Missense Mutation (SNP) | VAF 27/88 reads (31%) | SIFT tolerated (0.5); PolyPhen benign (0.021); catalogued as rs772529746, COSV64598000, COSV64599212; called by muse, mutect2, varscan2
- C1orf94 | c.770A>C p.K257T (on ENST00000488417 / NM_001134734.2; = p.K67T on NM_032884.5) | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.429); catalogued as COSV100974667, COSV100975231; called by muse, mutect2, varscan2
- CACNA1A | c.493T>G p.L165V | Missense Mutation (SNP) | VAF 51/177 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100800871; called by muse, mutect2, varscan2
- CADM1 | c.614T>G p.L205R | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100522090, COSV59013571; called by muse, mutect2, varscan2
- CALD1 | c.785A>C p.K262T | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.163); catalogued as COSV100724006; called by muse, mutect2, varscan2
- CAPZA3 | c.128T>G p.L43R | Missense Mutation (SNP) | VAF 35/75 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56851538; called by muse, mutect2, varscan2
- CBLN2 | c.605T>G p.L202R | Missense Mutation (SNP) | VAF 24/128 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54050077, COSV54052757, COSV54053612; called by muse, varscan2
- CDH10 | c.2198T>G p.L733R | Missense Mutation (SNP) | VAF 8/116 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100050052; called by muse, mutect2
- CDH2 | c.2618T>C p.L873P | Missense Mutation (SNP) | VAF 30/108 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99295658; called by muse, mutect2, varscan2
- CDH2 | c.1687T>C p.S563P | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV99295659; called by muse, mutect2, varscan2
- CDK14 | c.808T>G p.L270V (on ENST00000380050 / NM_001287135.2; = p.L252V on NM_012395.3) | Missense Mutation (SNP) | VAF 26/113 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV99723724; called by muse, mutect2, varscan2
- CHRM2 | c.953A>G p.E318G | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as COSV57783351; called by muse, mutect2, varscan2
- CHRNA4 | c.1685C>T p.P562L | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs200750362, COSV100937337; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CLCNKB | c.470G>T p.C157F | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.094); catalogued as rs1433595236, COSV100990188; called by muse, mutect2, varscan2
- CLEC9A | c.701A>C p.K234T | Missense Mutation (SNP) | VAF 24/161 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.263); catalogued as COSV100191135; called by muse, mutect2, varscan2
- CMPK2 | c.1199T>G p.L400R | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99878667; called by muse, mutect2, varscan2
- CNTN4 | c.82T>C p.F28L | Missense Mutation (SNP) | VAF 59/216 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.864); catalogued as COSV101281154; called by muse, mutect2, varscan2
- COL12A1 | c.4287A>C p.E1429D | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.497); catalogued as COSV100485398; called by muse, mutect2, varscan2
- COL24A1 | c.2375G>A p.G792E | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100992867; called by muse, mutect2, varscan2
- COP1 | c.1612+1G>A p.X538_splice | Splice Site (SNP) | VAF 38/151 reads (25%) | catalogued as rs1382241525, COSV100442693; called by muse, mutect2, varscan2
- CPED1 | c.101C>T p.T34I | Missense Mutation (SNP) | VAF 31/83 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as COSV100119972; called by muse, mutect2, varscan2
- CPNE8 | c.1104A>C p.K368N | Missense Mutation (SNP) | VAF 36/144 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as COSV58842375; called by muse, mutect2, varscan2
- CPS1 | c.4415T>G p.L1472R | Missense Mutation (SNP) | VAF 72/240 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.541); catalogued as rs756635859, COSV51802426; called by muse, mutect2, varscan2
- CRMP1 | c.1615T>C p.F539L | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as COSV100271305, COSV100271324; called by muse, mutect2, varscan2
- CSMD3 | c.3490T>C p.S1164P (on ENST00000297405 / NM_001363185.1; = p.S1060P on NM_052900.3) | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV99824614; called by muse, mutect2, varscan2
- CSRNP2 | c.1336_1338del p.E446del | In Frame Del (DEL) | VAF 13/49 reads (27%) | catalogued as rs1236073292; called by mutect2, pindel, varscan2
- CUBN | c.2109T>G p.P703= | Splice Region (SNP) | VAF 37/140 reads (26%) | catalogued as COSV100912042; called by muse, mutect2, varscan2
- DCAF12L1 | c.1392A>C p.*464Yext*2 | Nonstop Mutation (SNP) | VAF 19/36 reads (53%) | catalogued as COSV100948081; called by muse, mutect2, varscan2
- DCBLD2 | c.438A>C p.K146N | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.997); catalogued as COSV100471394; called by muse, mutect2, varscan2
- DCSTAMP | c.902T>C p.L301P | Missense Mutation (SNP) | VAF 42/192 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV52576825, COSV99886075; called by muse, mutect2, varscan2
- DDX60 | c.2504A>T p.N835I | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.009); catalogued as COSV67097437; called by muse, mutect2, varscan2
- DENND4A | c.4247C>T p.S1416L | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.715); catalogued as rs1161018429, COSV101475259; called by muse, mutect2, varscan2
- DNAH5 | c.3500C>G p.S1167C | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.325); catalogued as rs780756921, COSV99444954; called by muse, mutect2, varscan2
- DRGX | c.386A>C p.K129T | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.494); catalogued as COSV65136047; called by muse, mutect2, varscan2
- DSEL | c.1610A>G p.K537R | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT tolerated (0.58); PolyPhen benign (0.009); catalogued as COSV100025251; called by muse, mutect2
- DSEL | c.1414A>C p.S472R | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100025940, COSV59489055; called by muse, mutect2, varscan2
- DSEL | c.1184T>G p.L395R | Missense Mutation (SNP) | VAF 34/109 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100025252; called by muse, mutect2, varscan2
- EDARADD | c.291A>C p.K97N (on ENST00000334232 / NM_145861.4; = p.K87N on NM_080738.4) | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT tolerated (0.19); PolyPhen benign (0.036); catalogued as COSV100512539; called by muse, mutect2, varscan2
- ELMO1 | c.931A>G p.T311A | Missense Mutation (SNP) | VAF 33/84 reads (39%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.945); catalogued as COSV100163271; called by muse, mutect2, varscan2
- ELMO1 | c.569A>T p.K190M | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.22); PolyPhen benign (0.309); catalogued as COSV100163273, COSV100164764; called by muse, mutect2, varscan2
- ENAM | c.687A>C p.E229D | Missense Mutation (SNP) | VAF 43/134 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101252915; called by muse, mutect2, varscan2
- EPB41L5 | c.985G>A p.V329I | Missense Mutation (SNP) | VAF 47/146 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.835); catalogued as rs375364339; called by muse, mutect2, varscan2
- ERBB4 | c.3270A>C p.E1090D | Missense Mutation (SNP) | VAF 31/125 reads (25%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV61483958, COSV61511878; called by muse, mutect2, varscan2
- EVC | c.200A>T p.K67M | Missense Mutation (SNP) | VAF 37/138 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as COSV99381130; called by muse, mutect2, varscan2
- EYS | c.1004A>G p.E335G | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV100675654, COSV100676702; called by muse, mutect2, varscan2
- FAM209B | c.188T>C p.L63P | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.882); catalogued as rs202232100, COSV100990918; called by muse, mutect2
- FAT3 | c.6143A>G p.E2048G | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.967); catalogued as COSV99961836; called by muse, mutect2, varscan2
- FAT4 | c.14014A>C p.S4672R | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.571); catalogued as COSV100627217; called by muse, mutect2, varscan2
- FBN1 | c.1885G>A p.V629I | Missense Mutation (SNP) | VAF 28/104 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as rs140503215, COSV57331841; called by muse, mutect2, varscan2
- FCMR | c.381G>T p.E127D | Missense Mutation (SNP) | VAF 44/145 reads (30%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV100892807; called by muse, mutect2, varscan2
- FCRL3 | c.1388A>C p.H463P | Missense Mutation (SNP) | VAF 21/135 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.247); catalogued as COSV100942820; called by muse, mutect2, varscan2
- FCRL5 | c.1973G>A p.R658H | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT tolerated (0.32); PolyPhen benign (0.17); catalogued as rs376858048, COSV62512237; called by muse, mutect2, varscan2
- FDXR | c.896C>T p.A299V (on ENST00000293195 / NM_024417.5; = p.A305V on NM_004110.6) | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.049); catalogued as COSV99500567; called by muse, mutect2, varscan2
- FGF12 | c.316T>C p.F106L (on ENST00000454309 / NM_021032.5; = p.F44L on NM_004113.6) | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.985); catalogued as COSV99278883; called by muse, mutect2, varscan2
- FGF6 | c.274G>A p.V92M | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.622); catalogued as rs780277371, COSV99960144; called by muse, mutect2, varscan2
- FIGN | c.940A>G p.S314G | Missense Mutation (SNP) | VAF 20/99 reads (20%) | SIFT tolerated (0.76); PolyPhen benign (0.054); catalogued as COSV100291484; called by muse, mutect2, varscan2
- FLG | c.7598G>A p.R2533H | Missense Mutation (SNP) | VAF 80/322 reads (25%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs754603159, COSV64239282; called by muse, mutect2, varscan2
- FLNB | c.4888A>T p.T1630S | Missense Mutation (SNP) | VAF 23/93 reads (25%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.853); catalogued as COSV99911706; called by muse, mutect2, varscan2
- FMN2 | c.4887T>G p.N1629K | Missense Mutation (SNP) | VAF 15/109 reads (14%) | SIFT tolerated (0.9); PolyPhen benign (0.023); catalogued as rs1195070581, COSV60441719; called by muse, mutect2, varscan2
- FN1 | c.4999T>C p.S1667P | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100115913; called by muse, mutect2, varscan2
- FNBP1 | c.791A>T p.D264V | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.922); catalogued as COSV100852561; called by muse, mutect2, varscan2
- GABRA2 | c.277T>G p.F93V | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100733819; called by muse, mutect2, varscan2
- GABRB3 | c.314A>C p.N105T | Missense Mutation (SNP) | VAF 19/97 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.401); catalogued as COSV100158186; called by muse, mutect2, varscan2
- GABRG1 | c.76T>G p.L26V | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.899); catalogued as COSV99777381; called by muse, mutect2, varscan2
- GABRG3 | c.1327T>C p.S443P | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as COSV100404814; called by muse, mutect2, varscan2
- GALNT17 | c.149A>C p.N50T | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0.015); catalogued as COSV100352319, COSV61162864; called by muse, mutect2, varscan2
- GJD4 | c.253G>A p.V85I | Missense Mutation (SNP) | VAF 48/164 reads (29%) | SIFT tolerated (0.41); PolyPhen benign (0.143); catalogued as rs867645026, COSV100397089; called by muse, mutect2, varscan2
- GPC6 | c.322T>G p.F108V | Missense Mutation (SNP) | VAF 19/77 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.733); catalogued as rs748831483, COSV65542347; called by muse, mutect2, varscan2
- GPR179 | c.5062G>A p.D1688N (on ENST00000621958; = p.D1687N on NM_001004334.4) | Missense Mutation (SNP) | VAF 35/123 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs200260405; called by muse, mutect2, varscan2
- GRIN2C | c.155C>T p.P52L | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.044); catalogued as rs752702073, COSV99500565; called by muse, mutect2, varscan2
- GRXCR1 | c.93A>C p.E31D | Missense Mutation (SNP) | VAF 25/113 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.43); catalogued as COSV101295616; called by muse, mutect2, varscan2
- GSDMC | c.306A>C p.E102D | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.147); catalogued as COSV99415544; called by muse, mutect2, varscan2
- GZMA | c.436A>C p.T146P | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99696510; called by muse, mutect2
- HOXD13 | c.1010A>G p.K337R | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.855); catalogued as rs753726144, COSV101184136; called by mutect2, varscan2
- HTR1E | c.52A>G p.T18A | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV100540936; called by muse, mutect2, varscan2
- IL12RB2 | c.2326G>A p.D776N | Missense Mutation (SNP) | VAF 23/85 reads (27%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs774704366, COSV99254653; called by muse, mutect2, varscan2
- IL1RAPL2 | c.236A>C p.N79T | Missense Mutation (SNP) | VAF 20/33 reads (61%) | SIFT tolerated (0.73); PolyPhen benign (0.026); catalogued as COSV100780723; called by muse, mutect2, varscan2
- IQUB | c.1858C>T p.R620C | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.65); catalogued as rs141036933; called by muse, mutect2, varscan2
- IQUB | c.604A>C p.I202L | Missense Mutation (SNP) | VAF 44/195 reads (23%) | SIFT tolerated (0.39); PolyPhen benign (0.023); catalogued as COSV100226741; called by muse, mutect2, varscan2
- ISX | c.239A>C p.K80T | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.024); catalogued as COSV100434000, COSV58088631; called by muse, mutect2, varscan2
- ITPRID1 | c.2626A>C p.S876R | Missense Mutation (SNP) | VAF 23/88 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV60085891; called by muse, mutect2, varscan2
- ITSN2 | c.4204T>G p.S1402A | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.966); catalogued as COSV100742653; called by muse, mutect2, varscan2
- JRKL | c.1519C>T p.R507C | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as rs373707997; called by muse, mutect2, varscan2
- KRTAP10-3 | c.653A>G p.K218R | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.038); catalogued as COSV100551866; called by muse, mutect2, varscan2
- KY | c.916T>G p.F306V | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101414942; called by muse, mutect2, varscan2
- LAMA3 | c.9595G>A p.G3199R (on ENST00000313654 / NM_198129.4; = p.G1590R on NM_000227.6) | Missense Mutation (SNP) | VAF 33/108 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs775368078, COSV99333920; called by muse, mutect2, varscan2
- LCE1C | c.83A>G p.K28R | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated, low confidence (0.44); PolyPhen probably damaging (0.981); catalogued as rs758902168, COSV64219014; called by muse, mutect2, varscan2
- LCE1F | c.83A>C p.K28T | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV57669185; called by muse, mutect2, varscan2
- LINGO2 | c.998T>C p.L333P | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs376500553; called by muse, mutect2, varscan2
- LRP1B | c.12653A>C p.K4218T | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.494); catalogued as COSV104431704, COSV67206165; called by muse, mutect2, varscan2
- LRRK2 | c.4879T>G p.S1627A | Missense Mutation (SNP) | VAF 30/106 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.05); catalogued as COSV100109183; called by muse, mutect2, varscan2
- MAGEA6 | c.715T>G p.F239V | Missense Mutation (SNP) | VAF 61/105 reads (58%) | SIFT deleterious (0.01); PolyPhen benign (0.142); catalogued as rs782306683, COSV61448779; called by muse, mutect2, varscan2
- MAGEB1 | c.501A>C p.E167D | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV66775698; called by muse, mutect2, varscan2
- MAGEC3 | c.684A>C p.K228N | Missense Mutation (SNP) | VAF 37/65 reads (57%) | SIFT deleterious (0.04); PolyPhen benign (0.37); catalogued as COSV71610210; called by muse, mutect2, varscan2
- MCM6 | c.1342G>C p.A448P | Missense Mutation (SNP) | VAF 29/84 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51469564; called by muse, mutect2, varscan2
- MED12L | c.5542A>C p.T1848P | Missense Mutation (SNP) | VAF 36/188 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.216); catalogued as COSV99851501; called by muse, mutect2, varscan2
- MED13 | c.3619G>A p.D1207N | Missense Mutation (SNP) | VAF 6/121 reads (5%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.628); catalogued as COSV101180754, COSV67263138; called by muse, mutect2
- MEST | c.313T>G p.L105V | Missense Mutation (SNP) | VAF 52/187 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.04); catalogued as COSV56230674; called by muse, mutect2, varscan2
- MKRN2 | c.975dup p.A326Sfs*3 | Frame Shift Ins (INS) | VAF 21/85 reads (25%) | catalogued as rs1377010344; called by mutect2, pindel, varscan2
- MROH2B | c.2960A>C p.K987T | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.124); catalogued as COSV101270469; called by muse, mutect2, varscan2
- MRPS36 | c.206G>C p.G69A | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.874); catalogued as COSV99840943; called by muse, mutect2, varscan2
- MTUS2 | c.2192A>C p.K731T | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.799); catalogued as COSV70918043, COSV70919467, COSV70920728; called by muse, mutect2, varscan2
- MTUS2 | c.2259T>G p.Y753* | Nonsense Mutation (SNP) | VAF 6/43 reads (14%) | catalogued as COSV101462067, COSV101462371; called by muse, mutect2, varscan2
- MUC16 | c.8107A>C p.S2703R | Missense Mutation (SNP) | VAF 37/108 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.883); catalogued as COSV101198092; called by muse, mutect2, varscan2
- MYPN | c.1936G>A p.V646M | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT tolerated (0.15); PolyPhen benign (0.105); catalogued as rs772535532, COSV62738919; called by muse, mutect2, varscan2
- NBEA | c.468A>C p.E156D | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.956); catalogued as COSV100076744; called by muse, mutect2, varscan2
- NFIA | c.775C>A p.P259T | Missense Mutation (SNP) | VAF 32/100 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV100963225; called by muse, mutect2
- NPHP4 | c.1256A>G p.H419R | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT tolerated (0.76); PolyPhen benign (0.003); catalogued as COSV100976723; called by muse, mutect2, varscan2
- NR4A3 | c.53C>T p.A18V | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.485); catalogued as rs1391653942, COSV58245523; called by muse, mutect2, varscan2
- NTNG1 | c.41T>G p.V14G | Missense Mutation (SNP) | VAF 23/88 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.038); catalogued as COSV99635407; called by muse, mutect2, varscan2
- NUP205 | c.821C>T p.A274V | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as rs767119190, COSV53664059; called by muse, mutect2, varscan2
- OLFM3 | c.1283A>G p.E428G (on ENST00000338858 / NM_001288821.1; = p.E408G on NM_058170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 51/164 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV58796105; called by muse, mutect2, varscan2
- OLR1 | c.256T>C p.S86P | Missense Mutation (SNP) | VAF 40/152 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.276); catalogued as COSV100376287; called by muse, mutect2, varscan2
- OR13C4 | c.410A>C p.N137T | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.047); catalogued as COSV99469966; called by muse, mutect2, varscan2
- OR14A16 | c.340A>G p.T114A | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.902); catalogued as COSV100713693; called by muse, mutect2, varscan2
- OR1L1 | c.655T>C p.C219R (on ENST00000373686; = p.C169R on NM_001005236.3) | Missense Mutation (SNP) | VAF 31/199 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100542086; called by muse, mutect2, varscan2
- OR2AG1 | c.134T>A p.L45Q | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100264811, COSV100264817; called by muse, mutect2, varscan2
- OR2L13 | c.257C>A p.S86Y | Missense Mutation (SNP) | VAF 37/134 reads (28%) | SIFT tolerated (0.59); PolyPhen probably damaging (0.997); catalogued as COSV63552681; called by muse, mutect2, varscan2
- OR4D5 | c.337T>C p.F113L | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.643); catalogued as COSV100189731; called by muse, mutect2, varscan2
- OR4E2 | c.915A>C p.Q305H | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0.029); catalogued as COSV100330008; called by muse, mutect2, varscan2
- OR51B6 | c.619T>G p.L207V | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT tolerated (0.21); PolyPhen benign (0.17); catalogued as COSV100970575; called by muse, mutect2, varscan2
- OR5D16 | c.16A>G p.R6G | Missense Mutation (SNP) | VAF 24/130 reads (18%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs755221016, COSV65722006; called by muse, mutect2, varscan2
- OR6F1 | c.816A>C p.K272N | Missense Mutation (SNP) | VAF 22/103 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100128945; called by muse, mutect2, varscan2
- OR8H2 | c.401T>G p.V134G | Missense Mutation (SNP) | VAF 19/161 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.616); catalogued as COSV57946340; called by muse, mutect2, varscan2
- P2RY12 | c.425A>C p.K142T | Missense Mutation (SNP) | VAF 28/90 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs752204543, COSV99851500; called by muse, mutect2, varscan2
- PCDH15 | c.1892T>G p.V631G | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.653); catalogued as COSV100212884, COSV100215117; called by muse, mutect2, varscan2
- PCDH19 | c.3134G>A p.S1045N (on ENST00000373034 / NM_001184880.2; = p.S997N on NM_020766.3) | Missense Mutation (SNP) | VAF 13/23 reads (57%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.954); catalogued as COSV99718987; called by muse, mutect2, varscan2
- PCDHA5 | c.38T>A p.L13H | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.088); catalogued as COSV100972098; called by muse, mutect2, varscan2
- PCDHB1 | c.1333G>A p.V445I | Missense Mutation (SNP) | VAF 39/143 reads (27%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs1554267318, COSV60633061; called by muse, mutect2, varscan2
- PCDHB13 | c.2207T>A p.L736H | Missense Mutation (SNP) | VAF 25/164 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.933); catalogued as COSV99506705; called by muse, mutect2, varscan2
- PCDHB2 | c.223dup p.M75Nfs*7 | Frame Shift Ins (INS) | VAF 16/64 reads (25%) | catalogued as rs782086614; called by mutect2, varscan2
- PDGFD | c.145T>G p.L49V | Missense Mutation (SNP) | VAF 26/85 reads (31%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.73); catalogued as COSV100157798; called by muse, mutect2, varscan2
- PDZRN4 | c.1605A>C p.E535D (on ENST00000402685 / NM_001164595.2; = p.E277D on NM_013377.4) | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT tolerated (1); PolyPhen probably damaging (0.991); catalogued as COSV54209070; called by muse, mutect2, varscan2
- PGR | c.2488A>C p.I830L | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.364); catalogued as COSV99677413; called by muse, mutect2, varscan2
- PI15 | c.349T>G p.L117V | Missense Mutation (SNP) | VAF 36/162 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as COSV99477792, COSV99478194; called by muse, mutect2, varscan2
- PKHD1 | c.11567A>C p.K3856T | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs1160507513, COSV64396360, COSV64404691; called by muse, mutect2, varscan2
- PKHD1L1 | c.7982A>C p.E2661A | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as COSV101005359; called by muse, mutect2, varscan2
- PNLIP | c.889T>G p.F297V | Missense Mutation (SNP) | VAF 27/118 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100981624; called by muse, mutect2, varscan2
- POSTN | c.1547T>G p.L516R | Missense Mutation (SNP) | VAF 23/119 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV65712429, COSV65714152; called by muse, mutect2, varscan2
- POT1 | c.465T>A p.D155E | Missense Mutation (SNP) | VAF 25/92 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.136); catalogued as COSV100713994; called by muse, mutect2, varscan2
- POU4F3 | c.250A>T p.S84C | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.72); catalogued as COSV100046817; called by muse, mutect2, varscan2
- PPP2R3A | c.440A>G p.K147R | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.003); catalogued as rs1175810355, COSV99386434; called by muse, mutect2, varscan2
- PRAMEF4 | c.401A>C p.K134T | Missense Mutation (SNP) | VAF 55/201 reads (27%) | SIFT tolerated (0.61); PolyPhen benign (0.135); catalogued as COSV99339451; called by muse, mutect2, varscan2
- PRICKLE3 | c.1543C>A p.H515N | Missense Mutation (SNP) | VAF 23/31 reads (74%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.003); catalogued as rs1557099885, COSV100889887; called by muse, mutect2, varscan2
- PRPF3 | c.624A>C p.E208D | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.543); catalogued as COSV100254474; called by muse, mutect2, varscan2
- PSMD1 | c.921T>G p.F307L | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV100433335; called by muse, mutect2, varscan2
- PTPRT | c.3830A>C p.E1277A | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.566); catalogued as COSV100625202, COSV61959394, COSV61962998; called by muse, mutect2, varscan2
- RGL1 | c.2211A>C p.E737D (on ENST00000360851 / NM_001297672.2; = p.E772D on NM_015149.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV100486195; called by muse, mutect2, varscan2
- RGS4 | c.575A>T p.K192M | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.781); catalogued as COSV100905510; called by muse, mutect2, varscan2
- RHEBL1 | c.282A>C p.Q94H | Missense Mutation (SNP) | VAF 84/259 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as COSV99987918; called by muse, mutect2, varscan2
- RHO | c.1025C>T p.T342M | Missense Mutation (SNP) | VAF 16/96 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.52); catalogued as rs183318466, CM931220, COSV56214024; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- RNF112 | c.1234C>T p.R412C | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.649); catalogued as rs973963599, COSV101465387; called by muse, mutect2, varscan2
- ROBO3 | c.3272_3274del p.S1091del | In Frame Del (DEL) | VAF 10/48 reads (21%) | catalogued as rs752669677; called by pindel, varscan2
- ROR1 | c.1431A>C p.E477D | Missense Mutation (SNP) | VAF 41/185 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.562); catalogued as COSV100934912; called by muse, mutect2, varscan2
- RRAD | c.811C>T p.R271* | Nonsense Mutation (SNP) | VAF 23/60 reads (38%) | catalogued as COSV100233643; called by muse, mutect2, varscan2
- SALL1 | c.3090T>G p.I1030M | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.972); catalogued as COSV99171549; called by muse, mutect2, varscan2
- SAMD9L | c.2371A>G p.S791G | Missense Mutation (SNP) | VAF 20/114 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV100560322; called by muse, mutect2, varscan2
- SCN10A | c.194A>C p.K65T | Missense Mutation (SNP) | VAF 36/102 reads (35%) | SIFT tolerated (0.63); PolyPhen benign (0.145); catalogued as COSV101479264, COSV71860944, COSV71862775; called by muse, mutect2, varscan2
- SCN1A | c.1465T>G p.L489V | Missense Mutation (SNP) | VAF 21/134 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as CD163322, COSV100319275; called by muse, mutect2, varscan2
- SEMA4A | c.1426C>T p.P476S | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.034); catalogued as rs752357615, COSV100740428; called by muse, mutect2, varscan2
- SIGLEC5 | c.1390G>T p.A464S | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0.015); catalogued as rs866521402, COSV99707101; called by muse, mutect2, varscan2
- SLC24A2 | c.691T>G p.L231V | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99645776; called by muse, mutect2, varscan2
- SLCO1B1 | c.496T>C p.S166P | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT tolerated (0.26); PolyPhen benign (0.071); catalogued as rs751041337, COSV99917983; called by muse, mutect2, varscan2
- SLCO5A1 | c.1736A>C p.N579T | Missense Mutation (SNP) | VAF 39/103 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV99479389; called by muse, mutect2, varscan2
- SLIT2 | c.1316A>G p.K439R | Missense Mutation (SNP) | VAF 42/138 reads (30%) | SIFT tolerated (0.51); PolyPhen benign (0.101); catalogued as COSV56581108, COSV99880820; called by muse, mutect2, varscan2
- SLIT2 | c.3557T>G p.L1186R | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99880824; called by muse, mutect2, varscan2
- SLITRK1 | c.1690T>G p.F564V | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.05); catalogued as COSV100999777; called by muse, mutect2, varscan2
- SMO | c.1582A>G p.T528A | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT tolerated (0.5); PolyPhen probably damaging (0.992); catalogued as COSV50849705; called by muse, mutect2, varscan2
- SNCAIP | c.2621A>C p.N874T | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99747118; called by muse, mutect2, varscan2
- SPAG16 | c.1687A>G p.S563G | Missense Mutation (SNP) | VAF 42/148 reads (28%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.874); catalogued as rs1278165214, COSV100530109, COSV100536780; called by muse, mutect2, varscan2
- SPATA9 | c.566G>T p.C189F | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0); catalogued as COSV57223454; called by muse, mutect2, varscan2
- SPEF2 | c.3185A>C p.E1062A | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.054); catalogued as COSV100606298, COSV100608243; called by muse, mutect2, varscan2
- SPP1 | c.230A>C p.K77T (on ENST00000395080 / NM_001040058.2; = p.K63T on NM_000582.2) | Missense Mutation (SNP) | VAF 22/100 reads (22%) | SIFT tolerated (0.52); PolyPhen benign (0.012); catalogued as COSV99420833; called by muse, mutect2, varscan2
- STK33 | c.232A>T p.R78* | Nonsense Mutation (SNP) | VAF 6/105 reads (6%) | catalogued as COSV100173683; called by muse, mutect2
- SVEP1 | c.6746G>A p.R2249H | Missense Mutation (SNP) | VAF 35/131 reads (27%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.993); catalogued as rs796680406, COSV99928003; called by muse, mutect2, varscan2
- SYNE1 | c.16547A>G p.E5516G (on ENST00000367255 / NM_182961.4; = p.E5445G on NM_033071.3) | Missense Mutation (SNP) | VAF 44/162 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); catalogued as COSV99553104, COSV99576946; called by muse, mutect2, varscan2
- SYNE1 | c.13244T>G p.L4415R (on ENST00000367255 / NM_182961.4; = p.L4344R on NM_033071.3) | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99553112; called by muse, mutect2, varscan2
- SYNE1 | c.2789A>C p.K930T (on ENST00000367255 / NM_182961.4; = p.K937T on NM_033071.3) | Missense Mutation (SNP) | VAF 27/108 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.114); catalogued as rs1253895303, COSV99553116; called by muse, mutect2, varscan2
- TAS2R9 | c.119A>G p.D40G | Missense Mutation (SNP) | VAF 29/103 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.009); catalogued as rs188520221, COSV99553556; called by muse, mutect2, varscan2
- TDO2 | c.561A>C p.E187D | Missense Mutation (SNP) | VAF 36/85 reads (42%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as COSV101539714; called by muse, mutect2, varscan2
- TECTA | c.3569C>T p.P1190L | Missense Mutation (SNP) | VAF 72/284 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); catalogued as COSV99878571; called by muse, mutect2, varscan2
- TEK | c.824A>C p.K275T | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.701); catalogued as COSV101193144; called by muse, mutect2, varscan2
- TEX35 | c.219A>G p.I73M | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99274015; called by muse, mutect2, varscan2
- TG | c.4382A>G p.K1461R | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV99599005; called by muse, mutect2, varscan2
- TIMP3 | c.194A>G p.K65R | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV99830919; called by muse, mutect2, varscan2
- TIMP3 | c.398A>C p.K133T | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.321); catalogued as COSV99830920; called by muse, mutect2, varscan2
- TJP1 | c.409C>T p.H137Y | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as rs202151545, COSV100632308; called by muse, mutect2, varscan2
- TLE4 | c.1013A>G p.N338S | Missense Mutation (SNP) | VAF 32/115 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99511166, COSV99513080; called by muse, mutect2, varscan2
- TMEM132D | c.1571T>G p.L524R | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101242540; called by muse, mutect2, varscan2
- TMX2 | c.787C>T p.R263W | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.792); catalogued as rs778852347, COSV99559715; called by muse, mutect2, varscan2
- TNN | c.1589-2A>C p.X530_splice | Splice Site (SNP) | VAF 18/69 reads (26%) | catalogued as COSV99511066; called by muse, mutect2, varscan2
- TRIM26 | c.721G>A p.E241K | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.864); catalogued as rs757480189, COSV68963047; called by muse, mutect2, varscan2
- TTC21B | c.1796G>A p.G599E | Missense Mutation (SNP) | VAF 27/114 reads (24%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as rs751093986, COSV54631370, COSV99692282; called by muse, mutect2, varscan2
- TTC6 | c.1476A>C p.K492N (on ENST00000267368; = p.K1858N on NM_001310135.3) | Missense Mutation (SNP) | VAF 35/131 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.096); catalogued as rs1293272021, COSV99941534; called by muse, mutect2, varscan2
- TTN | c.6779T>G p.L2260R (on ENST00000591111; = p.L2214R on NM_003319.4) | Missense Mutation (SNP) | VAF 15/65 reads (23%) | PolyPhen probably damaging (0.999); catalogued as COSV100623271; called by muse, mutect2
- WASF3 | c.641T>G p.L214R | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.748); catalogued as COSV100098067; called by muse, mutect2, varscan2
- WDR45B | c.929-1G>A p.X310_splice | Splice Site (SNP) | VAF 6/28 reads (21%) | catalogued as COSV101124405; called by muse, mutect2
- WDR75 | c.940A>G p.I314V | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.09); catalogued as COSV100134018; called by muse, mutect2, varscan2
- WT1 | c.1340A>C p.K447T | Missense Mutation (SNP) | VAF 76/252 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.348); catalogued as COSV60076411, COSV99070045; called by muse, mutect2, varscan2
- XIRP2 | c.10032A>C p.E3344D (on ENST00000628543; = p.E3519D on NM_152381.6) | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.791); catalogued as rs1449476301, COSV99738393; called by muse, mutect2, varscan2
- ZBED9 | c.617A>C p.N206T | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.001); catalogued as COSV101509107, COSV101509408; called by muse, mutect2
- ZFAT | c.1072T>G p.F358V | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as COSV100914224; called by muse, mutect2, varscan2
- ZNF285 | c.518A>G p.E173G | Missense Mutation (SNP) | VAF 33/149 reads (22%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.864); catalogued as rs1267144616, COSV100449839; called by muse, mutect2, varscan2
- ZNF320 | c.1235T>G p.L412R | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.046); catalogued as COSV101206838, COSV67089037; called by muse, mutect2
- ZNF432 | c.275T>C p.L92S | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT tolerated (0.49); PolyPhen benign (0.157); catalogued as COSV99659061; called by muse, mutect2, varscan2
- ZNF790 | c.1400G>T p.R467L | Missense Mutation (SNP) | VAF 21/87 reads (24%) | SIFT tolerated (0.25); PolyPhen benign (0.232); catalogued as rs1269004806, COSV100764748, COSV63211861; called by muse, mutect2, varscan2
- ABCA5 | c.2873del p.N958Mfs*2 | Frame Shift Del (DEL) | VAF 16/56 reads (29%) | called by mutect2, pindel, varscan2
- CACNA1E | c.1088del p.N363Tfs*6 | Frame Shift Del (DEL) | VAF 16/53 reads (30%) | called by mutect2, pindel, varscan2
- CSMD1 | c.4976del p.P1659Qfs*17 (on ENST00000520002; = p.P1658Qfs*17 on NM_033225.6) | Frame Shift Del (DEL) | VAF 5/25 reads (20%) | called by mutect2, pindel, varscan2
- DDIT4L | c.540A>C p.K180N | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.658); called by muse, mutect2, varscan2
- IGKV3D-20 | c.160T>G p.L54V | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.284); called by muse, mutect2, varscan2
- IGLV1-36 | c.257A>C p.K86T | Missense Mutation (SNP) | VAF 26/130 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.455); called by muse, mutect2, varscan2
- PRAMEF14 | c.515A>G p.Y172C | Missense Mutation (SNP) | VAF 137/494 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ABCB4 | c.3369T>C p.S1123= (on ENST00000265723 / NM_018849.3; = p.S1116= on NM_000443.4) | Silent (SNP) | VAF 37/144 reads (26%) | catalogued as COSV99709718; called by muse, mutect2, varscan2
- ALDH5A1 | c.1317T>C p.T439= | Silent (SNP) | VAF 3/46 reads (7%) | catalogued as COSV100708723; called by muse, mutect2
- ARHGAP24 | c.213T>G p.S71= | Silent (SNP) | VAF 36/114 reads (32%) | catalogued as COSV101232946; called by muse, mutect2, varscan2
- CALB1 | c.115T>C p.L39= | Silent (SNP) | VAF 45/193 reads (23%) | catalogued as COSV99617925; called by muse, mutect2, varscan2
- CCR4 | c.327G>C p.L109= | Silent (SNP) | VAF 64/243 reads (26%) | catalogued as COSV100447271; called by muse, mutect2, varscan2
- CDH4 | c.1971C>T p.A657= | Silent (SNP) | VAF 21/74 reads (28%) | catalogued as rs200482576, COSV64675742; called by muse, mutect2, varscan2
- COL5A3 | c.3744C>T p.P1248= | Silent (SNP) | VAF 7/20 reads (35%) | catalogued as rs780165005, COSV99318222; called by muse, mutect2, varscan2
- CTNNA3 | c.2205G>A p.A735= | Silent (SNP) | VAF 11/84 reads (13%) | catalogued as rs745959148, COSV65523880; called by muse, mutect2, varscan2
- DCLK1 | c.1731T>G p.T577= | Silent (SNP) | VAF 17/54 reads (31%) | catalogued as COSV99709094; called by muse, mutect2, varscan2
- ERICH3 | c.4377T>C p.T1459= | Silent (SNP) | VAF 28/115 reads (24%) | catalogued as rs1174287164, COSV100443391; called by muse, mutect2, varscan2
- FGA | c.537T>G p.S179= | Silent (SNP) | VAF 16/59 reads (27%) | catalogued as COSV100120001; called by muse, mutect2, varscan2
- FST | c.738A>G p.E246= | Silent (SNP) | VAF 16/74 reads (22%) | catalogued as COSV99887020; called by muse, mutect2, varscan2
- GABBR2 | c.2241G>C p.L747= | Silent (SNP) | VAF 18/107 reads (17%) | catalogued as COSV99409171; called by muse, mutect2, varscan2
- GJD2 | c.606A>G p.Q202= | Silent (SNP) | VAF 11/60 reads (18%) | catalogued as COSV99290548; called by muse, mutect2
- GLT8D1 | c.525T>A p.I175= | Silent (SNP) | VAF 9/42 reads (21%) | catalogued as COSV99803516; called by muse, mutect2, varscan2
- GPR12 | c.513G>T p.L171= | Silent (SNP) | VAF 4/19 reads (21%) | catalogued as COSV101197941; called by muse, mutect2, varscan2
- GUCY1A2 | c.2098A>C p.R700= | Silent (SNP) | VAF 44/176 reads (25%) | catalogued as COSV99972683; called by muse, mutect2, varscan2
- HERC4 | c.156T>C p.D52= | Silent (SNP) | VAF 23/135 reads (17%) | catalogued as COSV101034237; called by muse, mutect2, varscan2
- HOXD10 | c.585G>A p.L195= | Silent (SNP) | VAF 9/35 reads (26%) | catalogued as COSV99981707; called by muse, mutect2, varscan2
- HS3ST4 | c.1203A>G p.E401= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as COSV100500048; called by muse, varscan2
- ITSN1 | c.4698C>T p.I1566= | Silent (SNP) | VAF 16/51 reads (31%) | catalogued as COSV101181215, COSV67157016; called by muse, mutect2, varscan2
- KCNV2 | c.804C>G p.T268= | Silent (SNP) | VAF 7/20 reads (35%) | catalogued as rs769345730, COSV101172501; called by muse, mutect2, varscan2
- KIAA0408 | c.1233T>C p.C411= | Silent (SNP) | VAF 16/71 reads (23%) | catalogued as rs772115810, COSV100846772; called by muse, mutect2, varscan2
- KIF21B | c.1353C>T p.R451= | Silent (SNP) | VAF 8/48 reads (17%) | catalogued as rs1255525237, COSV100143434; called by muse, mutect2, varscan2
- KIF21B | c.174C>T p.T58= | Silent (SNP) | VAF 11/40 reads (28%) | catalogued as COSV100143606; called by muse, mutect2, varscan2
- LINGO2 | c.999G>T p.L333= | Silent (SNP) | VAF 16/47 reads (34%) | catalogued as rs1440758907, COSV100430146, COSV58062156; called by muse, mutect2, varscan2
- LRRN1 | c.777G>T p.L259= | Silent (SNP) | VAF 24/89 reads (27%) | catalogued as COSV100076022; called by muse, mutect2, varscan2
- MAP2 | c.2430A>G p.L810= | Silent (SNP) | VAF 40/142 reads (28%) | catalogued as COSV99557822; called by muse, mutect2, varscan2
- MAP7D3 | c.963G>A p.A321= | Silent (SNP) | VAF 56/92 reads (61%) | catalogued as rs368859198, COSV100286139; called by muse, mutect2, varscan2
- MAPKBP1 | c.843A>G p.T281= (on ENST00000456763 / NM_001128608.2; = p.T275= on NM_014994.3) | Silent (SNP) | VAF 30/88 reads (34%) | catalogued as rs1330504575, COSV99528909; called by muse, varscan2
- MPEG1 | c.492T>G p.T164= | Silent (SNP) | VAF 40/119 reads (34%) | catalogued as rs1401378334, COSV99914996; called by muse, mutect2, varscan2
- MUC16 | c.18702T>C p.S6234= | Silent (SNP) | VAF 12/65 reads (18%) | catalogued as COSV101198091; called by muse, mutect2, varscan2
- NETO1 | c.324T>C p.F108= | Silent (SNP) | VAF 30/121 reads (25%) | catalogued as COSV100198196; called by muse, mutect2, varscan2
- NFIA | c.777A>G p.P259= | Silent (SNP) | VAF 31/98 reads (32%) | catalogued as COSV100963227; called by muse, mutect2
- NPAP1 | c.267T>C p.G89= | Silent (SNP) | VAF 11/37 reads (30%) | catalogued as rs1267155647, COSV100274774; called by muse, mutect2, varscan2
- NPAS1 | c.897A>G p.P299= | Silent (SNP) | VAF 10/41 reads (24%) | catalogued as rs748024424, COSV101463919; called by muse, mutect2, varscan2
- OGFRL1 | c.1020T>C p.T340= | Silent (SNP) | VAF 14/53 reads (26%) | catalogued as rs778660135, COSV64971630, COSV64972030; called by muse, mutect2, varscan2
- OR4C6 | c.190T>C p.L64= | Silent (SNP) | VAF 26/109 reads (24%) | catalogued as COSV58605224, COSV58606549; called by muse, mutect2, varscan2
- OR6C1 | c.681T>G p.P227= | Silent (SNP) | VAF 28/93 reads (30%) | catalogued as rs1466979435, COSV101110448; called by muse, mutect2, varscan2
- PLEC | c.13887C>G p.G4629= (on ENST00000322810 / NM_201380.4; = p.G4519= on NM_000445.5) | Silent (SNP) | VAF 3/16 reads (19%) | catalogued as COSV100510488; called by muse, mutect2
- PRUNE2 | c.1722A>G p.Q574= | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as COSV100944213; called by muse, mutect2, varscan2
- RGS12 | c.411C>T p.V137= | Silent (SNP) | VAF 36/76 reads (47%) | catalogued as rs1026320088, COSV100374724; called by muse, mutect2, varscan2
- RUNX1 | c.747C>G p.S249= (on ENST00000344691 / NM_001001890.3; = p.S276= on NM_001754.5) | Silent (SNP) | VAF 16/59 reads (27%) | catalogued as COSV100276486; called by muse, mutect2, varscan2
- SERPINB2 | c.297T>A p.A99= | Silent (SNP) | VAF 17/64 reads (27%) | catalogued as COSV100208171; called by muse, mutect2, varscan2
- SF3B1 | c.3636G>A p.L1212= | Silent (SNP) | VAF 19/74 reads (26%) | catalogued as COSV100133798; called by muse, mutect2
- SI | c.1815T>C p.N605= | Silent (SNP) | VAF 25/81 reads (31%) | catalogued as COSV100013950; called by muse, mutect2, varscan2
- SLC24A2 | c.243T>G p.G81= | Silent (SNP) | VAF 23/119 reads (19%) | catalogued as COSV99645777; called by muse, mutect2, varscan2
- SLC4A4 | c.1752G>A p.T584= (on ENST00000264485 / NM_001098484.3; = p.T540= on NM_003759.4) | Silent (SNP) | VAF 40/152 reads (26%) | catalogued as rs747153129, COSV99138936; called by muse, mutect2, varscan2
- SLC9A8 | c.1110T>A p.I370= | Silent (SNP) | VAF 28/76 reads (37%) | catalogued as COSV100846226; called by muse, mutect2, varscan2
- SORCS1 | c.1284A>G p.Q428= | Silent (SNP) | VAF 17/55 reads (31%) | catalogued as rs753043519, COSV53873607, COSV99543230; called by muse, mutect2, varscan2
- SOX1 | c.324C>T p.R108= | Silent (SNP) | VAF 9/29 reads (31%) | catalogued as rs1219290870, COSV58379597, COSV58379678; called by muse, mutect2
- ST8SIA4 | c.265T>C p.L89= | Silent (SNP) | VAF 14/59 reads (24%) | catalogued as rs1254215631, COSV51505649, COSV99185107; called by muse, mutect2, varscan2
- TECTA | c.3951A>G p.K1317= | Silent (SNP) | VAF 24/115 reads (21%) | catalogued as COSV99878573; called by muse, mutect2, varscan2
- TEX45 | c.1194G>A p.P398= | Silent (SNP) | VAF 7/31 reads (23%) | catalogued as rs776584000, COSV64463792, COSV64464433; called by muse, mutect2, varscan2
- TMPRSS11B | c.132T>G p.T44= | Silent (SNP) | VAF 7/37 reads (19%) | catalogued as COSV100219229; called by muse, mutect2
- TRPM1 | c.2478G>A p.A826= | Silent (SNP) | VAF 18/94 reads (19%) | catalogued as rs774603670, COSV99855327; called by muse, mutect2, varscan2
- TTN | c.82098G>A p.E27366= (on ENST00000591111; = p.E19942= on NM_003319.4) | Silent (SNP) | VAF 6/34 reads (18%) | catalogued as COSV100593972, COSV60421505; called by muse, mutect2, varscan2
- TTN | c.13725A>G p.K4575= (on ENST00000591111; = p.K3648= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 3/40 reads (8%) | catalogued as COSV100593976; called by muse, mutect2
- UBR1 | c.144A>T p.P48= | Silent (SNP) | VAF 40/132 reads (30%) | catalogued as COSV99316633; called by muse, mutect2, varscan2
- XIRP2 | c.2610A>G p.Q870= (on ENST00000628543; = p.Q1045= on NM_152381.6) | Silent (SNP) | VAF 11/42 reads (26%) | catalogued as COSV54705003, COSV99738390; called by muse, mutect2, varscan2
- ZNF141 | c.1158A>G p.K386= | Silent (SNP) | VAF 20/81 reads (25%) | catalogued as rs879971446, COSV53658798; called by muse, mutect2, varscan2
- ZNF304 | c.1674T>G p.P558= | Silent (SNP) | VAF 9/48 reads (19%) | catalogued as COSV99988390; called by muse, mutect2
- ZNF418 | c.2022T>C p.P674= | Silent (SNP) | VAF 18/74 reads (24%) | catalogued as COSV101268887; called by muse, mutect2, varscan2
- ZNF420 | c.372T>G p.T124= | Silent (SNP) | VAF 15/56 reads (27%) | catalogued as COSV100421141, COSV58494266; called by muse, mutect2, varscan2
- CPLANE1 | c.*3686A>C | 3'UTR (SNP) | VAF 13/59 reads (22%) | catalogued as COSV99949592; called by muse, mutect2, varscan2
- HERC2P3 | n.466A>C | RNA (SNP) | VAF 4/10 reads (40%) | called by mutect2, varscan2
- MGAT4B | c.98-106G>T | Intron (SNP) | VAF 25/61 reads (41%) | catalogued as COSV99482035; called by muse, mutect2, varscan2
- SV2C | c.-2A>C | 5'UTR (SNP) | VAF 4/30 reads (13%) | catalogued as COSV100455636; called by muse, mutect2, varscan2
- TTN | c.10360+1253T>G | Intron (SNP) | VAF 54/179 reads (30%) | catalogued as COSV59861821, COSV59870423; called by muse, mutect2, varscan2
